Gene-level copy-number profile of tumor specimen TCGA-XU-AAXV-01A from TCGA case TCGA-XU-AAXV, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 45.4 years (16,582 days).
Specimen TCGA-XU-AAXV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.9a38e9b4-1a14-4d0e-a844-d57a7d707527.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XU-AAXV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/d4d4abcc-94da-44b4-b495-8a8f4944fd2a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,820.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
